Somatic mutation profile of tumor specimen 0DOXGZ from CCDI case PBCCYX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 6.3 years (2,300 days).
Specimen 0DOXGZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ffa9b8c-238a-42ed-9fd7-78b9e0105cf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXG1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/790336e8-f1e6-4bde-a876-0def52107271

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTF2 | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 68/590 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.676); catalogued as COSV100940211; called by muse, mutect2, varscan2
- ZP2 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs894105056; called by muse, mutect2
- ZP4 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63912294; called by muse, mutect2, varscan2
- ASPM | c.2072A>T p.Y691F | Missense Mutation (SNP) | VAF 22/874 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2
- STT3B | c.2078G>T p.S693I | Missense Mutation (SNP) | VAF 66/473 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- MXD1 | c.*77C>A | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
